Somatic mutation profile of tumor specimen MP2PRT-PAVSKW-TMP1-A (aliquot MP2PRT-PAVSKW-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVSKW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,386 days).
Specimen MP2PRT-PAVSKW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c869b4e-ae03-4666-a251-4ec3c5fa64fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSKW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSKW-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6f467a9-f407-4e55-a7af-5d971c642810

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.6644C>T p.S2215F | Missense Mutation (SNP) | VAF 66/372 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEMIP | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 120/434 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs778862898, COSV54988859; called by muse, mutect2, varscan2
- DYTN | c.410G>A p.S137N | Missense Mutation (SNP) | VAF 75/376 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200720001; called by muse, mutect2, varscan2
- MYH8 | c.1640C>T p.T547M | Missense Mutation (SNP) | VAF 62/255 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs149040691; called by muse, mutect2, varscan2
- NHSL1 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1005620885, COSV58675800; called by muse, mutect2, varscan2
- PAX5 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 75/353 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100814524, COSV63913183; called by muse, mutect2, varscan2
- PLIN4 | c.470C>T p.T157M (on ENST00000301286; = p.T172M on NM_001367868.2) | Missense Mutation (SNP) | VAF 136/558 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs527463190, COSV56692704; called by muse, mutect2, varscan2
- SBNO2 | c.3509C>T p.A1170V | Missense Mutation (SNP) | VAF 235/803 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.742); catalogued as COSV62318605, COSV62320218; called by muse, mutect2, varscan2
- TCAF1 | c.2266G>A p.V756I | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1241972003; called by muse, mutect2, varscan2
- KCNH6 | c.1814_1815insT p.L606Afs*50 | Frame Shift Ins (INS) | VAF 206/798 reads (26%) | called by mutect2, pindel*, varscan2
- NUMA1 | c.25dup p.A9Gfs*14 | Frame Shift Ins (INS) | VAF 118/436 reads (27%) | called by mutect2, pindel, varscan2
- SERINC5 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEC2 | c.240C>T p.T80= | Silent (SNP) | VAF 100/229 reads (44%) | catalogued as rs1211112880, COSV99909590; called by muse, mutect2, varscan2
- PCDHGA2 | c.2139G>A p.A713= | Silent (SNP) | VAF 213/982 reads (22%) | catalogued as COSV53932471; called by muse, mutect2, varscan2
- ROBO2 | c.1755G>A p.L585= | Silent (SNP) | VAF 90/396 reads (23%) | called by muse, mutect2, varscan2
- ATXN8OS | n.499+1131A>T | Intron (SNP) | VAF 39/154 reads (25%) | called by muse, mutect2, varscan2
